Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AADU, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AADU-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: HCC – right posterior segment (S6-7) 6.0 cm sized

Specimen : Mass, Surrounding liver tissue

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Right hemihepatectomy and cholecystectomy

Organs:

Liver (17.5 x 11.5 x 9.0 cm, 647.0 gm)

Gallbladder (10.3 cm in length, 4.2 cm in diameter, and 0.4 cm in thickness)

Lesion:

[Liver]

A well-defined large round mass (4.7 x 4.5 x 5.0 cm)

Cut surface: Yellow to green, solid and firm mass without necrosis

Gross type:

HCC: Expanding nodular

A well-defined small multinodular mass (1.3 x 0.9 x 0.5 cm)

Cut surface: Yellowish tan, solid and firm mass without necrosis

Gross type:

HCC: Multinodular confluent

Resection margin: Not involved grossly (safety margin: 0.3 cm)

Others:

Satellite nodule: Yes

Remaining parenchyma: Pre-cirrhotic (stage 3)

[Gallbladder]

Multiple polyps with stone (0.7 x 0.6 x 0.6 cm)

Representative sections submitted

Gross photo: Present

Blocks

TB, T1-4, large tumor mass x 5

T5, separate nodule x 1

L, NB, liver parenchyma x 2

RM, resection margin x 1

GB, gallbladder x 1

MICROSCOPIC:

Hepatocellular carcinoma:

The worst differentiation III

The major differentiation II

Histologic type: Trabecular

Cell type: Hepatic

Fatty change: Yes (10-30 %)

Fibrous capsule formation: Yes

Capsular infiltration: No

Septum formation: Yes

Surgical resection margin invasion: No/ safety margin (0.3 cm)

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0

7/25/2014

[page 2 of 2]
Serosal invasion: No
Portal vein invasion: No
Microvessel invasion: Yes
Intrahepatic metastasis: Unknown
Multicentric occurrence: Present

NOT reported. Gross:

Liver, ectomy, hepatocellular carcinoma, well differentiated
T56000, P10, M81703, well differentiated
Gallbladder, ectomy, autolysis, cholesterol polyps, cholelithiasis
T57000, P10, M54001, cholesterol polyps, M30011
Lymph node, pericystic, biopsy, reactive hyperplasia
T08000, pericystic, P50, M72200

DIAGNOSIS:

Liver, right hemihepatectomy:
Hepatocellular carcinoma (Edmondson-steiner grade 2),
well-differentiated

Gallbladder, cholecystectomy:
Autolysis
Cholesterol polyps
Cholelithiasis

Lymph node, pericystic, biopsy:
Reactive hyperplasia (0/1)

Suggestion :

HPA Discrepancy		✓
First Malignancy History		✓

Source: NCI Genomic Data Commons file c84bc2bb-c130-43b3-bb1d-73a86e78a138 (TCGA-DD-AADU.5135A7C0-6CA4-404E-9649-E7B664EDD1B8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).